Gene-level copy-number profile of tumor specimen C3N-04155-01 from CPTAC case C3N-04155, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 76.8 years (28,060 days).
Specimen C3N-04155-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3ba9a0ec-797f-4196-9fe4-f68089aceff1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04155-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/232e8263-5736-4382-af93-e75368c8ab09

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 203; copy number 1: 1,472; copy number 2: 19,881; copy number 3: 24,841; copy number 4: 9,450; copy number 5: 1,225; copy number 6: 244; copy number 7: 231; copy number 8: 236; copy number 9: 291; copy number 10: 253; copy number 11: 92; copy number 12: 31; copy number 13: 1; copy number 14: 27; copy number 15: 4; copy number 16: 81; copy number 17: 9; copy number 18: 160; copy number 19: 92; copy number 20: 67; copy number 32: 15.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:9,621,764–9,769,513, 1 gene (within-gene range 0–3): AC060834.2.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr12:133,217,210–133,238,549, 4 genes: AC226150.1, ANHX, RNU6-717P, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,580 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,617,160–91,685,884, 3 genes, copy number 7 (within-gene range 6–7): LSP1P4, RNA5SP100, DRD5P1.
- chr3:168,008,689–198,123,232, 586 genes, copy number 8–32 (broad region; genes not listed).
- chr5:13,690,331–15,110,920, 19 genes, copy number 10: DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8.
- chr5:15,425,758–15,496,353, 2 genes, copy number 7: AC114964.2, AC114964.1.
- chr9:61,190,003–64,082,534, 76 genes, copy number 8–15 (broad region; genes not listed).
- chr17:60,122,642–60,135,743, 1 gene, copy number 10 (within-gene range 5–10): AC025048.2.
- chr17:60,135,039–60,550,798, 13 genes, copy number 10–11: AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1.
- chr17:62,626,031–68,524,949, 185 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr17:71,298,156–76,656,422, 177 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–41,207,539, 513 genes, copy number 9–20 (broad region; genes not listed).
- chr21:12,999,676–13,120,807, 5 genes, copy number 9–13: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 1,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
